Gene-level copy-number profile of tumor specimen TCGA-2G-AAHO-01A from TCGA case TCGA-2G-AAHO, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 30.7 years (11,230 days).
Specimen TCGA-2G-AAHO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6b78180e-c912-47fd-bd3c-dfdd15a3e45d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAHO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/a100af26-8885-4e64-b5f5-5fa5fb7cb70d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 680; copy number 2: 15,374; copy number 3: 23,509; copy number 4: 14,822; copy number 5: 2,748; copy number 6: 809; copy number 7: 61; copy number 8: 875; copy number 9: 33.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 969 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:90,383,721–91,556,848, 12 genes, copy number 7 (within-gene range 5–7): CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1.
- chr8:66,628,487–74,099,853, 126 genes, copy number 7–9 (broad region; genes not listed).
- chr12:66,767–34,249,958, 831 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 680. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
